Somatic mutation profile of tumor specimen TCGA-DX-A2J4-01A (aliquot TCGA-DX-A2J4-01A-32D-A21Q-09) from TCGA case TCGA-DX-A2J4, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 60.6 years (22,131 days).
Specimen TCGA-DX-A2J4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68d0e25a-44fb-4af8-9de2-9f787804e72a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A2J4-10A (Blood Derived Normal), aliquot TCGA-DX-A2J4-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99a467a9-3209-4a74-bc4b-5731761c9dbe

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 14, Silent 3, Frame Shift Ins 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATF7IP2 | c.903G>T p.E301D | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.861); catalogued as COSV100202739; called by muse, mutect2
- B4GALNT1 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 64/313 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs780620712; called by muse, varscan2
- CACNB1 | c.119G>C p.R40P | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100703511; called by muse, mutect2, varscan2
- ENPP5 | c.1403C>G p.A468G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV100040569; called by muse, mutect2, varscan2
- RAVER2 | c.608dup p.L204Ifs*3 | Frame Shift Ins (INS) | VAF 5/53 reads (9%) | catalogued as rs749647362; called by mutect2, pindel, varscan2
- RFTN2 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54387025, COSV54387981; called by muse, mutect2, varscan2
- ANKRD24 | c.3355G>T p.A1119S | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- AP3B1 | c.2023_2044del p.F675Rfs*53 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel
- EPB41L1 | c.1927C>T p.L643F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- HTT | c.2702T>G p.L901* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- PRKAA1 | c.151C>A p.H51N | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RCOR1 | c.530A>G p.N177S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- RPAP3 | c.1201G>A p.G401R | Missense Mutation (SNP) | VAF 228/380 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- RPAP3 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 137/250 reads (55%) | SIFT tolerated (0.51); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SIPA1L2 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMCHD1 | c.5721T>A p.D1907E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAF6L | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- KRT83 | c.336G>A p.K112= | Silent (SNP) | VAF 220/5210 reads (4%) | called by muse, mutect2
- KRT84 | c.450C>G p.L150= | Silent (SNP) | VAF 73/2162 reads (3%) | called by muse, mutect2
- TSPAN19 | c.732C>T p.I244= | Silent (SNP) | VAF 40/65 reads (62%) | catalogued as rs267603703; called by muse, mutect2, varscan2
